Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7836, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7836-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

1. Kidney, right, tumor #1, excision: Renal cell carcinoma with features of papillary RCC type 1 with solid and clear cell areas; see note.
2. Kidney, right, tumor #2, excision: Multiple foci of renal cell carcinoma with features of papillary RCC type 1 with solid areas; see note.

NOTE: The case will be discussed with [REDACTED] and a supplemental report will follow, if indicated.

CLINICAL INFORMATION: Brief Clinical History: [REDACTED] with HPRC and right renal mass
Specimen Taken For Protocol: 01 - Yes Allocate Order to Protocol:
[REDACTED]

PROCEDURE: Operative Findings: two right renal masses Post-Operative Diagnosis:
renal mass Pre-Operative Diagnosis: renal mass

SPECIMENS SUBMITTED: 1. TUMOR, #1
2. TUMOR, #2 Right Kidney

GROSS DESCRIPTION: Received for procurement labeled with the patient's name, medical record number, and further described as follows are:

1. "Tumor #1" is a 1.1 x 1.1 x 1 cm white soft tissue fragment. The cut surface is tan homogeneous. 60% is procured for the [REDACTED] a 0.1 cc amount is procured for electron microscopy, and the remainder is sent to Surgical

Patient Identification

[page 2 of 2]
[REDACTED]

Pathology. At Surgical Pathology, the specimen is received and matches the above description. It is serially sectioned and entirely submitted in cassette [REDACTED] for permanent processing.

2. "Tumor #2 right kidney" is a 2.5 x 2.2 x 2 cm soft tissue fragment with a white/tan, variegated cut surface. Attached normal parenchyma is seen. 35% is procured the [REDACTED] a 0.1 cc fragment is sent for electron microscopy, and the remainder is sent to [REDACTED]. At [REDACTED] the specimen is received and matches the above description and is entirely submitted in cassette [REDACTED] for permanent processing.

The above procurement was performed by [REDACTED] [REDACTED] on [REDACTED].

[REDACTED]

No consultants

[REDACTED]

Patient Identification

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 5928ada8-95b8-4083-bf5e-f37d85470d66 (TCGA-DW-7836.D04B8436-E888-42D1-9E9E-37754888704B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).